Gene-level copy-number profile of tumor specimen TCGA-RG-A7D4-01A from TCGA case TCGA-RG-A7D4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.3 years (25,302 days).
Specimen TCGA-RG-A7D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.310e4792-ccdc-49a6-a2e3-5d3dcd4f044b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RG-A7D4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4ba2e83-e566-4361-a647-b0f6d16b9936

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,881; copy number 3: 18,272; copy number 4: 13,808; copy number 5: 11,060; copy number 6: 8,392; copy number 7: 2,539; copy number 8: 2,488; copy number 9: 38; copy number 10: 1,232; copy number 11: 110.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RG-A7D4-01A-12D-A33P-01): tumor purity 0.35, ploidy 4.93, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,407 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–4,147,429, 95 genes, copy number 7 (broad region; genes not listed).
- chr5:62,403,972–62,628,582, 1 gene, copy number 7 (within-gene range 6–7): IPO11.
- chr5:62,512,246–181,342,213, 2,084 genes, copy number 7–8 (broad region; genes not listed).
- chr6:167,607–66,094,909, 1,568 genes, copy number 7–9 (broad region; genes not listed).
- chr6:128,883,138–129,516,566, 1 gene, copy number 8 (within-gene range 6–8): LAMA2.
- chr6:129,157,523–131,792,231, 29 genes, copy number 8: BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1, MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5.
- chr6:131,819,803–131,828,413, 3 genes, copy number 8: SELENOKP2, RN7SKP245, AL139805.1.
- chr6:151,225,550–170,738,536, 335 genes, copy number 7 (broad region; genes not listed).
- chr8:58,411,359–145,066,685, 1,342 genes, copy number 10–11 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 8 (broad region; genes not listed).
- chr20:87,250–31,259,632, 573 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
